HCMI case HCM-SANG-1337-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/029399ba-21fa-4e49-8ddf-f73e4704858a

Demographics
Sex at birth: male; Days to birth: -27,211 days (74.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Uicc pathologic m: M0; Uicc pathologic n: N2a; Uicc pathologic t: T3; Uicc staging system edition: 7th.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes; Vascular invasion type: Intramural.
   Recorded as not given: neoadjuvant treatment (type not reported).

Molecular and laboratory tests
- CEA: 1.5 ng/mL.
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Positive.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples)
- Sample HCM-SANG-1337-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
- Sample HCM-SANG-1337-C18-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples HCM-SANG-1337-C18-85A-01D-A80T-32, HCM-SANG-1337-C18-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
